Somatic mutation profile of tumor specimen TCGA-D6-A6ES-01A (aliquot TCGA-D6-A6ES-01A-12D-A31L-08) from TCGA case TCGA-D6-A6ES, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 50.4 years (18,408 days).
Specimen TCGA-D6-A6ES-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad3f4d01-dc7d-4693-8c7e-e9d70b9e840c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D6-A6ES-10A (Blood Derived Normal), aliquot TCGA-D6-A6ES-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3ab8710-ceae-4ca4-9a46-6ab4fcd5179e

The open-access MAF lists 212 somatic variants for this specimen: 159 protein-altering or splice-affecting, 52 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 140, Silent 52, Nonsense Mutation 9, Frame Shift Ins 3, Splice Site 3, Frame Shift Del 2, Nonstop Mutation 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.80-1G>C p.X27_splice | Splice Site (SNP) | VAF 17/33 reads (52%) | catalogued as rs786204914, CS157862, COSV64288482; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.2205G>C p.E735D | Missense Mutation (SNP) | VAF 60/203 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV100229626; called by muse, mutect2, varscan2
- AADAC | c.697C>G p.Q233E | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV99233557; called by muse, mutect2, varscan2
- ABCA2 | c.6250G>A p.E2084K (on ENST00000614293; = p.E2054K on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/223 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.056); catalogued as rs762366113, COSV99688609; called by muse, mutect2, varscan2
- ABCC12 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs372957171; called by muse, mutect2, varscan2
- ACAN | c.5431G>A p.G1811R | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV61372153; called by muse, mutect2, varscan2
- ACOXL | c.1052G>C p.G351A | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101096140; called by muse, mutect2
- ADGRG4 | c.3791C>T p.S1264F | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.543); catalogued as COSV99796267; called by muse, mutect2, varscan2
- ADRA2C | c.358G>C p.G120R | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.33); PolyPhen probably damaging (1); catalogued as COSV100342848, COSV57466824, COSV57467981; called by muse, mutect2, varscan2
- AIM2 | c.766C>T p.Q256* | Nonsense Mutation (SNP) | VAF 25/75 reads (33%) | catalogued as COSV100931167; called by muse, mutect2, varscan2
- ALOX12 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99277974, COSV99278557; called by muse, mutect2, varscan2
- ANO10 | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.893); catalogued as COSV52734681; called by muse, mutect2, varscan2
- APOM | c.566G>C p.*189Sext*15 | Nonstop Mutation (SNP) | VAF 16/77 reads (21%) | catalogued as COSV101023018, COSV65524677; called by muse, mutect2, varscan2
- ARHGAP31 | c.1893G>C p.R631S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV99957876; called by muse, mutect2
- ARID1A | c.1708C>A p.P570T | Missense Mutation (SNP) | VAF 116/378 reads (31%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs752518436, COSV100253785; called by muse, mutect2, varscan2
- ASPH | c.2170G>C p.E724Q | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100370804, COSV57983764; called by muse, mutect2, varscan2
- ASXL1 | c.2642G>C p.R881T | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.462); catalogued as COSV100041655; called by muse, varscan2
- ASXL1 | c.2693G>A p.W898* | Nonsense Mutation (SNP) | VAF 43/123 reads (35%) | catalogued as COSV60120196; called by muse, varscan2
- ASXL3 | c.5020G>T p.E1674* | Nonsense Mutation (SNP) | VAF 33/99 reads (33%) | catalogued as COSV52461969, COSV99327010; called by muse, mutect2, varscan2
- ATP6V1G3 | c.99G>C p.L33F | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99811108; called by muse, mutect2, varscan2
- BCL6B | c.384C>A p.H128Q | Missense Mutation (SNP) | VAF 90/129 reads (70%) | SIFT tolerated (0.32); PolyPhen benign (0.1); catalogued as COSV99546952; called by muse, mutect2, varscan2
- BICD2 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.174); catalogued as COSV100794390; called by muse, mutect2, varscan2
- BMI1 | c.862C>T p.H288Y | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.284); catalogued as COSV64958860; called by muse, mutect2
- BPI | c.1376C>A p.P459Q (on ENST00000262865; = p.P455Q on NM_001725.3) | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368496977, COSV53403586, COSV99481034; called by muse, mutect2, varscan2
- C3AR1 | c.644C>G p.S215C | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV99369097; called by muse, mutect2, varscan2
- C5 | c.3031G>A p.E1011K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99798991; called by muse, mutect2, varscan2
- C5orf58 | c.118G>C p.D40H | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99253707; called by muse, mutect2, varscan2
- CACNA1B | c.4885G>T p.D1629Y | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99500436; called by muse, mutect2, varscan2
- CASP8AP2 | c.5428G>C p.D1810H | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.063); catalogued as COSV99387510, COSV99387661; called by muse, mutect2, varscan2
- CCDC105 | c.676-1G>A p.X226_splice | Splice Site (SNP) | VAF 16/35 reads (46%) | catalogued as COSV99479694; called by muse, mutect2, varscan2
- CCDC116 | c.1031C>G p.S344* | Nonsense Mutation (SNP) | VAF 27/89 reads (30%) | catalogued as COSV99489532; called by muse, mutect2, varscan2
- CCDC33 | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99166282; called by muse, mutect2, varscan2
- CCN4 | c.762C>A p.C254* | Nonsense Mutation (SNP) | VAF 30/115 reads (26%) | catalogued as COSV99137551; called by muse, mutect2, varscan2
- CHD9 | c.4177G>C p.E1393Q | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.979); catalogued as rs746510251, COSV99529882; called by muse, mutect2, varscan2
- CHMP7 | c.789G>A p.E263= | Splice Region (SNP) | VAF 80/141 reads (57%) | catalogued as COSV100500804; called by muse, mutect2, varscan2
- COL6A3 | c.7308G>C p.E2436D | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV99802235; called by muse, mutect2, varscan2
- CRACR2A | c.187G>T p.D63Y | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52913989, COSV99365624; called by muse, mutect2, varscan2
- CRTC1 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 125/348 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV100119690; called by muse, mutect2, varscan2
- CRYBG2 | c.4443C>G p.I1481M | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100367066; called by muse, mutect2, varscan2
- CUBN | c.9931G>C p.D3311H | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV100913708, COSV64721464; called by muse, mutect2, varscan2
- CYP2D6 | c.1412G>T p.G471V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100637407; called by muse, mutect2, varscan2
- DAB2IP | c.2502G>C p.Q834H (on ENST00000408936; = p.Q806H on NM_032552.3) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); catalogued as COSV99406531; called by muse, mutect2, varscan2
- DAB2IP | c.2875G>C p.D959H (on ENST00000408936; = p.D931H on NM_032552.3) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as COSV99406534; called by muse, mutect2, varscan2
- DENND6B | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.551); catalogued as rs1424718785, COSV100834353; called by muse, varscan2
- DGKK | c.536C>A p.P179Q | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV101053259; called by muse, mutect2, varscan2
- DNAH11 | c.2814G>C p.L938F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.642); catalogued as COSV100181339, COSV60948987; called by muse, mutect2
- DSG4 | c.2104G>T p.A702S | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as rs147049549, COSV100356508; called by muse, mutect2, varscan2
- DZIP1L | c.2157G>C p.E719D | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV100551799, COSV59521364; called by muse, mutect2, varscan2
- EIF3G | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99463034; called by muse, mutect2, varscan2
- ENDOD1 | c.796C>G p.Q266E | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.192); catalogued as COSV99566892; called by muse, mutect2, varscan2
- ENOPH1 | c.169A>C p.S57R | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99908847; called by muse, mutect2, varscan2
- EPB41 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.03); catalogued as COSV100549580; called by muse, varscan2
- EPB41 | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 69/228 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.117); catalogued as COSV100549584; called by muse, varscan2
- EPHA7 | c.231G>T p.M77I | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as COSV100992561; called by muse, mutect2, varscan2
- ERCC6L2 | c.359A>G p.N120S | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1428222125, COSV99999071; called by muse, mutect2, varscan2
- FAM71E1 | c.415C>T p.R139W (on ENST00000600100 / NM_001308429.2; = p.R123W on NM_138411.3) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs895120268, COSV58542313; called by muse, mutect2, varscan2
- FCGBP | c.6513C>A p.H2171Q | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs1367361988; called by muse, mutect2, varscan2
- FOXN2 | c.392A>C p.K131T | Missense Mutation (SNP) | VAF 67/221 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100489549; called by muse, mutect2, varscan2
- FREM1 | c.4313G>A p.R1438Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs368346957; called by muse, mutect2, varscan2
- GALNT1 | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99322597; called by mutect2, varscan2
- GPATCH8 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.15); catalogued as rs758164012, COSV100132927; called by muse, mutect2, varscan2
- GREB1 | c.74C>G p.S25C | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99304000; called by muse, mutect2, varscan2
- GRK7 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99380377, COSV99380440; called by muse, mutect2, varscan2
- GUCY2C | c.2004C>G p.I668M | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV99664257; called by muse, mutect2, varscan2
- HADH | c.757G>T p.G253C | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100531644, COSV58851071; called by muse, mutect2, varscan2
- HDLBP | c.2846A>T p.D949V | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100192044; called by muse, mutect2, varscan2
- HERC2 | c.12103C>T p.Q4035* | Nonsense Mutation (SNP) | VAF 35/99 reads (35%) | catalogued as COSV99877467; called by muse, mutect2, varscan2
- HINFP | c.719C>T p.T240I | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs754166978, COSV100640898; called by muse, mutect2, varscan2
- HIP1R | c.1838G>A p.R613Q | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753493991, COSV99459413; called by muse, mutect2, varscan2
- HLX | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as rs751088009, COSV65045195, COSV65045833; called by muse, mutect2, varscan2
- IRF3 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs760057796, COSV99881800; called by muse, varscan2
- KANK1 | c.3553G>A p.D1185N | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT tolerated (0.32); PolyPhen benign (0.103); catalogued as rs775551364, COSV100620168; called by muse, mutect2, varscan2
- KCNAB1 | c.434G>A p.G145E (on ENST00000490337 / NM_172160.3; = p.G134E on NM_003471.3) | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100205262; called by muse, mutect2, varscan2
- KCND3 | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.37); catalogued as rs760710842, COSV56180280, COSV56191155; called by muse, mutect2, varscan2
- KIAA1109 | c.1153T>A p.L385I | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.978); catalogued as COSV99191448; called by muse, mutect2, varscan2
- KIF21A | c.4801A>T p.S1601C (on ENST00000361418 / NM_001378440.1; = p.S1588C on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/241 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100735757; called by muse, mutect2, varscan2
- KMT2D | c.2759C>G p.S920C | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.122); catalogued as COSV99986464; called by muse, mutect2, varscan2
- LCA5L | c.425G>C p.R142P | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99903952; called by muse, mutect2, varscan2
- LCE5A | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as COSV100524347; called by muse, mutect2, varscan2
- LDHD | c.1291C>G p.L431V | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.15); catalogued as COSV100097650; called by muse, mutect2, varscan2
- LRP2 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.79); catalogued as rs777216431, COSV99786454; called by muse, mutect2, varscan2
- LRRIQ3 | c.851T>C p.L284P | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV100599580; called by muse, mutect2, varscan2
- LVRN | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.676); catalogued as COSV63497610; called by muse, mutect2, varscan2
- MACF1 | c.2403C>G p.F801L | Missense Mutation (SNP) | VAF 35/117 reads (30%) | catalogued as COSV58381107; called by muse, mutect2, varscan2
- MACF1 | c.8645C>G p.S2882C | Missense Mutation (SNP) | VAF 25/70 reads (36%) | catalogued as COSV57143519, COSV99247390; called by muse, mutect2, varscan2
- MAGEC1 | c.1493C>A p.S498Y | Missense Mutation (SNP) | VAF 96/144 reads (67%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.001); catalogued as COSV53581588, COSV99596773; called by muse, mutect2, varscan2
- MAGI3 | c.1339C>T p.Q447* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | catalogued as COSV100290700; called by muse, mutect2, varscan2
- MCF2L2 | c.2337G>C p.E779D | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV100194185; called by muse, mutect2, varscan2
- MLNR | c.210del p.T71Pfs*59 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as COSV54532636; called by mutect2, pindel, varscan2
- MYOM1 | c.989G>A p.S330N | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.093); catalogued as COSV99868764; called by muse, mutect2
- NALCN | c.1507G>T p.G503* | Nonsense Mutation (SNP) | VAF 55/154 reads (36%) | catalogued as COSV99218369; called by muse, mutect2, varscan2
- NFE2L3 | c.1299C>G p.I433M | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV99284099; called by muse, mutect2, varscan2
- NLRP4 | c.304C>G p.H102D | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100017366; called by muse, mutect2, varscan2
- NOL9 | c.783G>C p.L261F | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as COSV66627149; called by muse, mutect2, varscan2
- NOP56 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100250381; called by muse, mutect2, varscan2
- NOTCH3 | c.4730T>C p.V1577A | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as COSV99659218; called by muse, mutect2, varscan2
- NOVA1 | c.933C>A p.D311E | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.98); catalogued as COSV99948948; called by muse, mutect2, varscan2
- NUDT5 | c.648C>G p.F216L | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.111); catalogued as COSV100036739; called by muse, mutect2
- OBP2B | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.69); PolyPhen benign (0.18); catalogued as COSV100922950; called by muse, mutect2, varscan2
- OR1K1 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV99474413; called by muse, mutect2, varscan2
- P2RX7 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99947841; called by muse, mutect2, varscan2
- PANK1 | c.1024G>A p.G342R (on ENST00000307534 / NM_148977.2; = p.G117R on NM_138316.4) | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100285505, COSV100285869; called by muse, mutect2, varscan2
- PAPPA2 | c.2750C>T p.P917L | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100868793, COSV62790466; called by muse, mutect2, varscan2
- PARS2 | c.160G>C p.D54H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV100988347; called by muse, mutect2, varscan2
- PCDHA9 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 67/178 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV65324208, COSV65330053; called by muse, mutect2, varscan2
- PCDHB8 | c.772A>G p.I258V | Missense Mutation (SNP) | VAF 59/573 reads (10%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.001); catalogued as rs782580710, COSV50830190; called by muse, mutect2, varscan2
- PCED1B | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV101423694; called by muse, mutect2, varscan2
- PCNX1 | c.4481C>T p.S1494L | Missense Mutation (SNP) | VAF 77/232 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs767549741, COSV99457601; called by muse, mutect2, varscan2
- PHACTR2 | c.815A>G p.K272R | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); catalogued as rs1262440456, COSV99992516; called by muse, mutect2, varscan2
- PLEKHG4 | c.2230G>A p.E744K | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58573913; called by muse, mutect2, varscan2
- POLQ | c.5090C>T p.S1697F | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.202); catalogued as COSV99953148; called by muse, mutect2, varscan2
- POLR2G | c.54C>A p.F18L | Missense Mutation (SNP) | VAF 114/360 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV100080202; called by muse, mutect2, varscan2
- PPP1R21 | c.1492C>G p.L498V | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.998); catalogued as COSV99682714; called by muse, mutect2, varscan2
- PTGER3 | c.601G>T p.V201F | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.247); catalogued as COSV100139813; called by muse, mutect2, varscan2
- PTPN14 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as COSV100873009; called by muse, mutect2, varscan2
- RBM8A | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.065); catalogued as COSV57162387; called by muse, mutect2, varscan2
- RYR3 | c.6304C>G p.R2102G | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101215034, COSV66779787; called by muse, mutect2, varscan2
- S100A7 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100906765; called by muse, mutect2, varscan2
- SCGN | c.102G>C p.E34D | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.142); catalogued as rs749383125, COSV100618887; called by muse, mutect2, varscan2
- SHANK3 | c.3449C>T p.A1150V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.344); catalogued as rs775925256, COSV99438184; called by muse, mutect2, varscan2
- SIM1 | c.319A>G p.T107A | Missense Mutation (SNP) | VAF 72/217 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99492924; called by muse, mutect2, varscan2
- SLC25A23 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 122/256 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99902689; called by muse, varscan2
- SLC25A42 | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs755219312, COSV100588255; called by muse, mutect2, varscan2
- SLC36A3 | c.204G>C p.K68N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100077960; called by muse, mutect2, varscan2
- SLC38A10 | c.2372G>A p.R791H | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs745356876, COSV99918017; called by muse, mutect2, varscan2
- SORCS3 | c.644C>T p.T215M | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs769758204, COSV100865131; called by muse, mutect2, varscan2
- SPDEF | c.149C>T p.T50M | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.306); catalogued as rs747037762, COSV100927772; called by muse, mutect2, varscan2
- SRSF3 | c.257G>C p.R86T | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100244990, COSV59670563; called by muse, mutect2, varscan2
- STON2 | c.2598C>G p.H866Q (on ENST00000649389 / NM_001366849.2; = p.H809Q on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV99965268; called by muse, mutect2, varscan2
- SULF1 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs769068348, COSV52688767; called by muse, mutect2, varscan2
- TAX1BP1 | c.822G>C p.K274N | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99604949; called by muse, mutect2, varscan2
- TCERG1 | c.1495A>G p.I499V | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs143498728; called by muse, mutect2, varscan2
- TDG | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs149084574; called by muse, mutect2, varscan2
- TFAP2A | c.1313G>A p.R438K (on ENST00000482890; = p.R430K on NM_001032280.3) | Missense Mutation (SNP) | VAF 142/364 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV60237992, COSV60238387; called by muse, mutect2, varscan2
- THEMIS2 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100198188; called by muse, mutect2, varscan2
- TRIO | c.6294C>G p.I2098M | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1164482398, COSV100711109; called by muse, mutect2, varscan2
- TRPV2 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0.012); catalogued as COSV100641181, COSV100641421; called by muse, mutect2, varscan2
- UCP2 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 47/82 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs576685655, COSV60105082; called by muse, mutect2, varscan2
- VSIG2 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs765251797, COSV52517777, COSV52517790; called by muse, mutect2, varscan2
- WDFY3 | c.7031G>T p.W2344L | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV99886133; called by muse, mutect2, varscan2
- WDR59 | c.2623C>G p.L875V | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV100049799; called by muse, mutect2, varscan2
- WDR62 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs766074970, COSV99544374; called by muse, mutect2, varscan2
- XPO7 | c.1513G>A p.G505S | Missense Mutation (SNP) | VAF 66/131 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.185); catalogued as rs568743752, COSV99382189; called by muse, mutect2, varscan2
- XYLT1 | c.2392C>A p.L798I | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); catalogued as COSV99763623; called by muse, mutect2, varscan2
- YEATS2 | c.1690C>G p.L564V | Missense Mutation (SNP) | VAF 52/235 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.492); catalogued as COSV100528414; called by muse, mutect2, varscan2
- YEATS2 | c.4133T>C p.V1378A | Missense Mutation (SNP) | VAF 122/271 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.081); catalogued as COSV100528415; called by muse, mutect2, varscan2
- ZBTB12 | c.999C>G p.I333M | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV100977059; called by muse, mutect2, varscan2
- ZEB2 | c.2794C>G p.L932V | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as COSV100357138; called by muse, mutect2, varscan2
- ZNF23 | c.1090T>C p.Y364H | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1188457626, COSV100612094, COSV100612299; called by muse, mutect2, varscan2
- ZNF25 | c.239-1G>A p.X80_splice | Splice Site (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100224822, COSV56923744; called by muse, mutect2, varscan2
- ZNF284 | c.296C>G p.S99C | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV101399122; called by muse, mutect2, varscan2
- ZNF521 | c.1615C>A p.L539I | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.85); PolyPhen benign (0.043); catalogued as COSV100833592; called by muse, mutect2, varscan2
- ZSCAN21 | c.4A>G p.M2V | Missense Mutation (SNP) | VAF 100/348 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV99461354; called by muse, mutect2, varscan2
- ANKS1B | c.479del p.K160Sfs*18 | Frame Shift Del (DEL) | VAF 18/59 reads (31%) | called by mutect2, pindel, varscan2
- CGB8 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- E2F3 | c.1359_1360insC p.E454Rfs*12 | Frame Shift Ins (INS) | VAF 38/143 reads (27%) | called by mutect2, pindel*, varscan2
- FRG2C | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 26/219 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0.047); called by muse, mutect2
- HSP90AA1 | c.1254_1257dup p.C420Kfs*8 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by pindel, varscan2
- LAMA5 | c.10976_10977dup p.A3660Pfs*7 | Frame Shift Ins (INS) | VAF 8/26 reads (31%) | called by pindel, varscan2
- ASB4 | c.531G>A p.T177= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs1466185391, COSV57943348; called by muse, mutect2, varscan2
- C15orf39 | c.1440C>T p.A480= | Silent (SNP) | VAF 40/115 reads (35%) | catalogued as COSV100641513; called by muse, mutect2, varscan2
- C1QBP | c.504C>T p.F168= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as rs774258991, COSV99852267; called by muse, mutect2, varscan2
- CCDC88A | c.3021C>T p.L1007= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV99711347; called by muse, mutect2, varscan2
- CD109 | c.3882C>G p.L1294= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as COSV54651255, COSV99754575; called by muse, mutect2, varscan2
- CDNF | c.270C>T p.D90= | Silent (SNP) | VAF 52/152 reads (34%) | catalogued as rs147677694; called by muse, mutect2, varscan2
- CNTLN | c.2442G>A p.V814= | Silent (SNP) | VAF 32/56 reads (57%) | catalogued as rs1564066867, COSV99266066; called by muse, mutect2, varscan2
- COP1 | c.609G>A p.K203= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100443033, COSV100444048; called by muse, mutect2, varscan2
- COX19 | c.6G>C p.S2= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV100700454; called by muse, mutect2, varscan2
- CYP2D6 | c.1209G>C p.L403= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV100637408, COSV62245854; called by muse, mutect2, varscan2
- DOP1B | c.5178C>G p.L1726= | Silent (SNP) | VAF 42/123 reads (34%) | catalogued as COSV101215900; called by muse, mutect2, varscan2
- DUSP15 | c.864C>T p.A288= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs748335110, COSV99640341; called by muse, mutect2, varscan2
- DYNLL2 | c.219C>T p.F73= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV74093382; called by muse, mutect2, varscan2
- EHMT1 | c.1557C>G p.L519= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as rs1376714202, COSV100604389; called by muse, mutect2, varscan2
- FBXO39 | c.522G>A p.L174= | Silent (SNP) | VAF 38/90 reads (42%) | catalogued as COSV100386317; called by muse, mutect2, varscan2
- FOXM1 | c.261C>T p.I87= | Silent (SNP) | VAF 41/125 reads (33%) | catalogued as rs11548398, COSV100700929; called by muse, mutect2, varscan2
- GDF7 | c.1287C>T p.D429= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs772860181, COSV55348601; called by muse, mutect2, varscan2
- GRM7 | c.312G>T p.R104= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs1392652247, COSV63170825; called by muse, mutect2, varscan2
- HOXD13 | c.423G>A p.S141= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV101184364; called by muse, mutect2, varscan2
- KCND2 | c.336C>T p.I112= | Silent (SNP) | VAF 77/239 reads (32%) | catalogued as COSV58575209, COSV58592459; called by muse, mutect2, varscan2
- KIF26B | c.1113C>T p.C371= | Silent (SNP) | VAF 34/112 reads (30%) | catalogued as rs373998722; called by muse, mutect2, varscan2
- LILRA4 | c.138C>G p.T46= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as COSV99393455; called by muse, mutect2, varscan2
- LPIN1 | c.360G>A p.L120= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV99878331; called by muse, mutect2, varscan2
- LRRC39 | c.825C>T p.F275= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as COSV61583636; called by muse, mutect2, varscan2
- NFIX | c.333G>A p.K111= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV62178180; called by muse, mutect2, varscan2
- NSD2 | c.351C>T p.I117= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV100374047; called by muse, mutect2, varscan2
- NSUN2 | c.807C>A p.V269= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV99243321, COSV99243503; called by muse, mutect2, varscan2
- OR13D1 | c.831G>C p.S277= | Silent (SNP) | VAF 37/114 reads (32%) | catalogued as rs369937407; called by muse, mutect2, varscan2
- OR8H2 | c.426C>T p.L142= | Silent (SNP) | VAF 67/202 reads (33%) | catalogued as rs767146909, COSV57947311; called by muse, mutect2, varscan2
- PLCH2 | c.435C>A p.T145= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as COSV99615358, COSV99617395; called by muse, mutect2, varscan2
- PRRX1 | c.723G>A p.V241= | Silent (SNP) | VAF 40/102 reads (39%) | catalogued as COSV99510484; called by muse, mutect2, varscan2
- RDH12 | c.525G>A p.S175= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as rs756315539, COSV50822561, COSV99961759; called by muse, mutect2, varscan2
- RNGTT | c.1491C>T p.P497= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV99667645; called by muse, mutect2, varscan2
- SACS | c.2733C>T p.T911= | Silent (SNP) | VAF 40/111 reads (36%) | catalogued as rs199702597; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC28A3 | c.1155A>G p.P385= | Silent (SNP) | VAF 42/81 reads (52%) | catalogued as rs752828191, COSV100883367; called by muse, mutect2, varscan2
- SLC45A3 | c.609C>G p.L203= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV100901369; called by muse, mutect2, varscan2
- SLC52A3 | c.324C>T p.F108= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV99448494; called by muse, mutect2, varscan2
- SMPD1 | c.1137C>T p.L379= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV100193196; called by muse, mutect2, varscan2
- SMPDL3B | c.825C>T p.F275= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs781670041, COSV65854818; called by muse, mutect2
- SMYD1 | c.1053G>A p.L351= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV101352543; called by muse, mutect2, varscan2
- TBX22 | c.384G>A p.K128= | Silent (SNP) | VAF 44/63 reads (70%) | catalogued as COSV100960977, COSV64785344; called by muse, mutect2, varscan2
- TBX3 | c.1128C>T p.D376= (on ENST00000257566 / NM_016569.4; = p.D356= on NM_005996.4) | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV99984194; called by muse, mutect2
- TG | c.1446G>A p.Q482= | Silent (SNP) | VAF 51/208 reads (25%) | catalogued as COSV55068525, COSV99603781; called by muse, mutect2, varscan2
- TMEM63C | c.1251C>G p.L417= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV100029872; called by muse, mutect2, varscan2
- TTN | c.58671G>A p.V19557= (on ENST00000591111; = p.V12133= on NM_003319.4) | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs1212789505, COSV100634362; called by muse, mutect2, varscan2
- U2SURP | c.396G>C p.V132= | Silent (SNP) | VAF 56/239 reads (23%) | catalogued as COSV101204603; called by muse, mutect2, varscan2
- USP33 | c.1857C>T p.F619= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as COSV100657277; called by muse, mutect2, varscan2
- WDR81 | c.3888C>T p.L1296= (on ENST00000409644 / NM_001163809.2; = p.L245= on NM_152348.4) | Silent (SNP) | VAF 41/111 reads (37%) | catalogued as rs145262105; called by muse, mutect2, varscan2
- WDR81 | c.5382C>T p.I1794= (on ENST00000409644 / NM_001163809.2; = p.I743= on NM_152348.4) | Silent (SNP) | VAF 30/99 reads (30%) | catalogued as rs867568129, COSV100489329; called by muse, mutect2, varscan2
- ZFHX4 | c.2121T>C p.S707= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as COSV99268828; called by muse, mutect2, varscan2
- ZNF786 | c.831C>T p.F277= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV100303041; called by muse, mutect2, varscan2
- ZNF791 | c.270G>A p.V90= | Silent (SNP) | VAF 65/216 reads (30%) | catalogued as COSV100589174; called by muse, mutect2, varscan2
- SCPEP1 | c.-1C>G | 5'UTR (SNP) | VAF 7/24 reads (29%) | catalogued as COSV99228046; called by muse, mutect2, varscan2
